Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A7NG, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A7NG-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN FOURTEEN (14) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN SIX (6) LYMPH NODES EXAMINED.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7 WITH TERTIARY GLEASON PATTERN 5.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.3 CM.
- C. THE CARCINOMA INVOLVES APPROXIMATELY 5% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS FOCAL EXTRACAPSULAR EXTENSION.
- E. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE ANTERIOR LEFT MID REGION (SLIDE 3V).
- F. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- G. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- H. PERINEURAL INVASION IS IDENTIFIED.
- I. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- J. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- K. PATHOLOGIC TNM STAGE: pT3a N0 MX.
- L. TNM HISTOLOGIC GRADE = G3.
- M. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

PART 4: URINARY BLADDER, NECK, LEFT POSTERIOR, BIOPSY

- A. BENIGN FIBROMUSCULAR TISSUE, NO PROSTATIC TISSUE IS IDENTIFIED.
- B. NO MALIGNANCY IS IDENTIFIED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA: PSA value: 5.3

- INVASIVE CA IDENTIFIED?: Yes
- TUMOR HISTOLOGY: Adenocarcinoma NOS
- PRIMARY GLEASON GRADE: 3
- SECONDARY GLEASON GRADE: 4
- GLEASON SUM SCORE: 7
- GLEASON 4/5 PERCENTAGE: 20%
- WEIGHT OF PROSTATE: 31.41gm
- TUMOR SIZE: Maximum dimension: 1.3 cm
- LOBE LATERALITY: Right and Left Lobes
- PERCENT OF SPECIMEN INVOLVED BY TUMOR: 5 - 25%
- MULTIFOCAL DISEASE: Yes
- HIGH GRADE PIN: Yes - NOS
- EXTRAPROSTATIC EXTENSION: Yes - Focal
- PERINEURAL INVASION: Yes
- ANGIOLYMPHATIC INVASION: No
- SEMINAL VESICLE INVASION: No
- SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
- LYMPH NODES EXAMINED: 20
- LYMPH NODES POSITIVE: 0
- T STAGE, PATHOLOGIC: pT3a
- N STAGE, PATHOLOGIC: pN0
- M STAGE, PATHOLOGIC: pMX
- HISTOLOGIC GRADE: G2, Moderately differentiated

ICD-O-3
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
9/24/13

Source: NCI Genomic Data Commons file 0d433104-538b-4173-b06d-37db6158fa14 (TCGA-EJ-A7NG.05993405-656B-4DB6-98BC-8359E16AC6AB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).